Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A20C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A20C-06A (Metastatic).

[page 1 of 2]
N/A
N/A
N/A
N/A
N/A N/A N/A

DOB/Age/Sex: years Male
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY SUPPLEMENTARY REPORT

SUPPLEMENTARY REPORT

Immunostains show that the tumour cells are weakly positive for S100 and negative for HMB45. Ki67 is positive in 2-20% of tumour cells (average 10%). These results are consistent with melanoma.

SUPPLEMENTARY SUMMARY

Skin, excision, right back: **Metastatic melanoma**, Please see report.

REPORTED BY

1CD-0-3

Melanoma, NOS 8720/3

Site: Skin, back C44.5

hw 3/30/11

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Team Study Metastatic melanoma. 1. Histopathology, 50% tissue to be processed (1 x H&E S100, HMB45 (red chromogen). (2). 50% frozen ASAP, to Team tissue bank. For ! to report. Copy to Dr

Tumour (R) back (upper).

MACROSCOPIC DESCRIPTION

(Dr t).

"RIGHT BACK". An unorientated ellipse of skin 48 x 10mm to a thickness of 35mm. A 25 x 14 x 16mm is identified in the deep subcutis abutting deep margin. One slice fixed for H&E. Remainder divided between Team and tumour banks. The remaining fixed tumour measures 10x10 x 7 mm. All of the tumour embedded.

- A. Ends.
- B. Tumour.
- C. Tumour and overlying skin.
- D. One section of skin from the middle.

MICROSCOPIC REPORT

Dr

Sections of skin including subcutis show a malignant tumour in the subcutis consistent with metastatic melanoma. The tumor is circumscribed and includes foci of necrosis (about 10%). It is composed of a sheet-like growth of epithelioid cells with vesicular nuclei and small eosinophilic nucleoli. Mitoses are present. The tumour extends very close to a peripheral margin.

Immunostains for S100, HMB 45 and Ki67 are pending (on block B- best block for further stains).

A seborrheic keratosis is also present.

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

SUMMARY

Skin, excision, right back: Metastatic melanoma, Please see report.

REPORTED BY

Source: NCI Genomic Data Commons file a6107663-7eed-4d63-88b0-8465ceacfdbe (TCGA-EE-A20C.F625D202-CF68-4EEF-A962-360AEA6978CB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).